Somatic mutation profile of tumor specimen MBCProject_1244_T1_WES (aliquot MBCProject_1244_T1_WES_1) from CMI case MBCProject_1244, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 44.8 years (16,350 days).
Specimen MBCProject_1244_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3490924-de93-4b07-adaa-a4b5df11ccd4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1244_SALIVA (Saliva), aliquot MBCProject_1244_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83ede442-6a23-484a-beaa-f01f543025fd

The open-access MAF lists 66 somatic variants for this specimen: 28 protein-altering or splice-affecting, 16 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 16, Intron 14, 3'UTR 4, Frame Shift Ins 3, Frame Shift Del 3, RNA 2, 5'Flank 2, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 35/186 reads (19%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 19/79 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATAD3A | c.1019C>T p.T340M | Missense Mutation (SNP) | VAF 42/313 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs552002436, COSV100186156; called by muse, mutect2, varscan2
- CDH9 | c.1341C>A p.D447E | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50287574; called by mutect2, varscan2
- ENOX2 | c.1145G>A p.R382Q (on ENST00000338144 / NM_001382520.1; = p.R353Q on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.421); catalogued as rs762259000, COSV57659205; called by mutect2, varscan2
- LRRC27 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs140670374; called by mutect2, varscan2
- MAP3K5 | c.3152G>A p.R1051Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV62890767; called by mutect2, varscan2
- MTO1 | c.1156A>C p.M386L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs997481152, COSV64773224; called by muse, mutect2
- MTSS1 | c.875C>T p.S292L | Missense Mutation (SNP) | VAF 61/316 reads (19%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.566); catalogued as rs533015192, COSV100274225, COSV61499020; called by muse, mutect2, varscan2
- PSEN2 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 30/338 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1302750366; called by muse, mutect2
- ZNF835 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 158/256 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369264555; called by muse, mutect2, varscan2
- ASL | c.91dup p.D31Gfs*42 | Frame Shift Ins (INS) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- ATP2B3 | c.2696T>G p.L899R | Missense Mutation (SNP) | VAF 158/458 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BANP | c.568dup p.C190Lfs*107 (on ENST00000286122; = p.C159Lfs*107 on NM_017869.4) | Frame Shift Ins (INS) | VAF 17/125 reads (14%) | called by mutect2, pindel, varscan2
- CDH9 | c.1339G>T p.D447Y | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- CEP250 | c.4390del p.D1464Tfs*2 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | called by mutect2, varscan2
- CSMD2 | c.6840dup p.I2281Dfs*30 | Frame Shift Ins (INS) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- CSN3 | c.326_337del p.R109_N112del | In Frame Del (DEL) | VAF 6/47 reads (13%) | called by mutect2, pindel
- ESCO1 | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by mutect2, varscan2
- FAM120C | c.447C>G p.Y149* | Nonsense Mutation (SNP) | VAF 55/153 reads (36%) | called by muse, mutect2, varscan2
- KRTAP4-4 | c.244C>G p.Q82E | Missense Mutation (SNP) | VAF 187/3528 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.018); called by muse, mutect2
- MCM2 | c.2090C>T p.A697V | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MRTO4 | c.127T>G p.F43V | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- PCK2 | c.1007A>G p.D336G | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.86); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTGR2 | c.388del p.G131Efs*3 | Frame Shift Del (DEL) | VAF 3/20 reads (15%) | called by pindel, varscan2
- SOX13 | c.260A>G p.K87R | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTLL11 | c.181T>A p.C61S | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, varscan2
- TUBB6 | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- C1R | c.1404C>T p.P468= (on ENST00000536053 / NM_001354346.2; = p.P454= on NM_001733.7) | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as rs1364385149; called by muse, mutect2, varscan2
- CELA2B | c.504T>G p.A168= | Silent (SNP) | VAF 20/57 reads (35%) | called by muse, mutect2, varscan2
- CRX | c.369G>A p.T123= | Silent (SNP) | VAF 64/146 reads (44%) | catalogued as rs368752695; called by muse, mutect2, varscan2
- EPB41L1 | c.939G>T p.R313= | Silent (SNP) | VAF 57/155 reads (37%) | called by muse, mutect2, varscan2
- FGD1 | c.882C>T p.S294= | Silent (SNP) | VAF 62/291 reads (21%) | catalogued as rs976496714; called by muse, mutect2, varscan2
- FLNB | c.3051C>T p.D1017= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs747054973; called by mutect2, varscan2
- KLHL30 | c.366C>T p.C122= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs556056703; called by muse, mutect2, varscan2
- MMP9 | c.1251G>T p.A417= | Silent (SNP) | VAF 49/207 reads (24%) | called by muse, varscan2
- PRSS27 | c.294G>A p.P98= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as rs763509095; called by muse, mutect2, varscan2
- PTPDC1 | c.417C>T p.G139= (on ENST00000375360 / NM_177995.3; = p.G191= on NM_152422.4) | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as rs1270330432; called by muse, mutect2, varscan2
- RP1 | c.2871C>G p.P957= | Silent (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- SLC5A6 | c.678C>T p.G226= | Silent (SNP) | VAF 20/210 reads (10%) | catalogued as rs760320309, COSV60160113; called by mutect2, varscan2
- TCAP | c.294G>A p.K98= | Silent (SNP) | VAF 317/888 reads (36%) | catalogued as rs761888264; called by muse, mutect2, varscan2
- TENM2 | c.6798C>T p.D2266= (on ENST00000518659 / NM_001122679.2; = p.D2027= on NM_001080428.3) | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as rs200885156; called by muse, varscan2
- UHMK1 | c.159C>G p.L53= | Silent (SNP) | VAF 21/136 reads (15%) | catalogued as COSV56419839; called by muse, mutect2, varscan2
- ZC3H13 | c.2284C>A p.R762= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as rs1328514144, COSV54458604, COSV54463281; called by mutect2, varscan2
- ARHGAP8 | c.299+278T>C | Intron (SNP) | VAF 12/66 reads (18%) | catalogued as rs1199925933, COSV104396514; called by muse, varscan2
- CD55 | c.1081+1172T>C | Intron (SNP) | VAF 10/86 reads (12%) | catalogued as rs1260729418; called by muse, varscan2
- COX6A1P2 | n.65G>A | RNA (SNP) | VAF 41/204 reads (20%) | catalogued as rs1254480886; called by muse, mutect2, varscan2
- DNAJC19 | c.*690A>G | 3'UTR (SNP) | VAF 8/60 reads (13%) | catalogued as rs1370714837, COSV104423365; called by muse, mutect2, varscan2
- FAM3A | c.127+452T>C | Intron (SNP) | VAF 6/44 reads (14%) | called by mutect2, varscan2
- HSD11B1L | c.204+255A>G | Intron (SNP) | VAF 4/24 reads (17%) | called by mutect2, varscan2
- LCA5 | c.1231+45_1231+47delinsA | Intron (DEL) | VAF 3/21 reads (14%) | called by pindel, varscan2*
- MBD3 | c.*2898A>G | 3'UTR (SNP) | VAF 6/36 reads (17%) | called by mutect2, varscan2
- MMAB | c.197-1151C>G | Intron (SNP) | VAF 4/15 reads (27%) | catalogued as rs1040360774; called by muse, varscan2
- MYPN | chr10:68106669 del A | 5'Flank (DEL) | VAF 3/24 reads (13%) | catalogued as rs543263308; called by pindel, varscan2
- NVL | c.285-1280A>G | Intron (SNP) | VAF 9/71 reads (13%) | called by muse, varscan2
- OSCAR | chr19:54102851 C>G | 5'Flank (SNP) | VAF 25/60 reads (42%) | catalogued as rs1324591234; called by muse, mutect2, varscan2
- PKNOX1 | c.*2038T>C | 3'UTR (SNP) | VAF 13/96 reads (14%) | catalogued as rs1335844212; called by muse, varscan2
- R3HDM2 | c.*446A>G | 3'UTR (SNP) | VAF 6/50 reads (12%) | catalogued as rs1453353142; called by mutect2, varscan2
- RBL2 | c.993-400A>G | Intron (SNP) | VAF 6/48 reads (13%) | catalogued as rs1426585233; called by mutect2, varscan2
- SNX29P2 | n.1156A>G | RNA (SNP) | VAF 22/250 reads (9%) | catalogued as rs1430353079; called by muse, varscan2
- SUMO1 | c.12+6842T>G | Intron (SNP) | VAF 16/90 reads (18%) | catalogued as rs758916105, COSV104432441; called by muse, mutect2
- SYTL2 | c.1459+3214T>C | Intron (SNP) | VAF 7/39 reads (18%) | catalogued as rs997169544; called by muse, mutect2, varscan2
- TEX49 | c.79+8597G>C | Intron (SNP) | VAF 4/24 reads (17%) | catalogued as rs74318967; called by mutect2, varscan2
- TUBGCP2 | c.616+586A>G | Intron (SNP) | VAF 9/85 reads (11%) | called by muse, varscan2
- YIPF3 | c.395+329G>T | Intron (SNP) | VAF 10/94 reads (11%) | catalogued as rs1383044718, COSV104411955; called by mutect2, varscan2
- ZNF273 | c.326-4267T>C | Intron (SNP) | VAF 18/170 reads (11%) | called by muse, varscan2
